Surgical pathology report (de-identified scan), TCGA case TCGA-XY-A8S3, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Spectrum Health, specimen TCGA-XY-A8S3-01B (Primary Tumor).

[page 1 of 4]
Research Gross Description

year-old with testicular mass_

Research Dx

Testicle, left, orchiectomy:

Mixed germ cell tumor.

See comment and case summary.

*ccsc ICD O-3
Carcinoma embryonal NOS 9070/3
Tumor, mixed germ cell 9085/3
Site: Testis NOS C62.9
9/11/14*

CASE SUMMARY FOR TESTIS (RADICAL ORCHIECTOMY):

Serum tumor markers: LDH 165 U/L; AFP 96.9 ng/ml; HCG elevated

Tumor focality: Unifocal

Tumor size: See below

Greatest dimension: 2.5 cm

Additional measurements: 2x2 cm

Macroscopic extent of tumor: Confined to testis

Histologic type: Mixed germ cell tumor (80% embryonal, 15% yolk sac, 5% choriocarcinoma)

Margins:

Spermatic cord margin: Benign

Other margins: N/A

Microscopic tumor extension: Confined to testis

Lymph-Vascular invasion: Yes

Pathologic staging (pTNM):

Primary tumor: pT2: Tumor limited to the testis with vascular/lymphatic invasion

Regional lymph nodes: X

Distant metastasis: N/A

Serum Tumor Markers: S1

Additional pathologic findings: Microlithiasis and intratubular germ cell neoplasia

AJCC Staging (7th edition) pT2

COMMENT

Properly controlled immunohistochemical studies were performed. CD30 and OCT 3/4 highlight the embryonal carcinoma. Glypican 3 and AFP highlight the yolk sac tumor while HGG highlights a small foci of choriocarcinoma. OCT 3/4 also highlights intratubular germ cell neoplasia.

Research QC

Tumor T1:

60% tumor nuclei (all embryonal)

less than one% necrosis

40% normal (stroma)

Per TSS - T1 = 100% embryonal.

Tumor T2:

50% tumor nuclei (all embryonal)

0% necrosis

50% normal stroma

Tumor T3:

75% tumor nuclei (of tumor nuclei, 25% choriocarcinoma, 75% embryonal)

0% necrosis

25% normal stroma

*Per TSS - T3 = 25% choriocarcinoma
75% embryonal*

Tumor T4:

50% tumor nuclei (all embryonal)

[page 2 of 4]
0% necrosis
50% normal stroma

Normal N1:
100% testis

Research Specimen

—

Specimen Process Time

Blood draw time:
Plasma frozen time:
Serum frozen time:
Buffy coat frozen time:

Cold ischemia start time:
Formalin fixation start time:
Total cold ischemia time:
Formalin fixation stopped time:
Total formalin fixation time:

Specimen Weight

T1-41 mg, T2-48 mg, T3-35 mg, T4-53 mg
N1-63 mg, N2-36 mg

Specimen Size

Plasma x 2
Serum x 1
Buffy coat x 1

Cryovials x 8
Normal x 4
Tumor x 4

FFPE x 8
Normal x 4
Tumor x 4

Study

Patient Consent

Yes

[page 3 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____

____ TSS Unique Patient Identifier. _____

Completed By (Interviewer Name on OpenClinica): _____

____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Mixed 80% embryonal, 15% yolk sac, 5% Chorio carcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	TT 100% (all) embryonal	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The portion of the tumor sampled for our biorepository was taken in sections. This section of tumor was evaluated by the surgical pathologist contained additional tumor tissue composed of additional subtypes	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

____ TSS Reviewing Pathologist or Biorepository Director

____ Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

____ Principal Investigator Signature

____ Date

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

T3

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Mixed 80% embryonal, 15% yolk sac, 5% choriocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Mixed 25% choriocarcinoma 75% embryonal	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The portion of the tumor sampled for our biorepository was taken in sections. The overall tumor evaluated by the surgical pathologist contained additional tumor tissue composed of additional subtypes.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 1cb0ec83-d532-4ddd-b21e-337ee2ce4c5c (TCGA-XY-A8S3.B3863E49-FC08-4A62-80E3-559167242CA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).